Somatic mutation profile of tumor specimen C3L-01352-01 (aliquot CPT0071150010) from CPTAC case C3L-01352, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 76.3 years (27,874 days).
Specimen C3L-01352-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5d4f52d-e8bf-420c-b9e6-b23b52eba7de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01352-31 (Blood Derived Normal), aliquot CPT0071980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de2d5900-e032-4f7d-b3be-e5053f5fdd00

The open-access MAF lists 113 somatic variants for this specimen: 81 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 20, Frame Shift Del 6, 5'UTR 5, Nonsense Mutation 4, Intron 3, 5'Flank 2, Frame Shift Ins 2, Splice Region 1, Splice Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTLA | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 32/138 reads (23%) | catalogued as rs780433132, COSV57938030; called by muse, mutect2, varscan2
- C12orf40 | c.1136G>C p.R379T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100210459; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 35/176 reads (20%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- CDH15 | c.2079G>C p.Q693H | Missense Mutation (SNP) | VAF 148/570 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99228712; called by muse, mutect2, varscan2
- CDH17 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as rs772250943; called by muse, mutect2, varscan2
- EPB41L4A | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs868831826; called by muse, mutect2, varscan2
- FTL | c.433A>G p.M145V | Missense Mutation (SNP) | VAF 104/465 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1038871067; called by muse, mutect2, varscan2
- GADD45A | c.45-6G>A | Splice Region (SNP) | VAF 51/145 reads (35%) | catalogued as rs768317163; called by muse, mutect2, varscan2
- GAPVD1 | c.4165A>C p.T1389P (on ENST00000394104; = p.T1398P on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/423 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1475102621, COSV52922173; called by muse, mutect2, varscan2
- HCN4 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 133/508 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1454748709, CM104901, COSV56082775; called by muse, mutect2, varscan2
- IGSF9B | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100318186, COSV100318259; called by muse, mutect2
- KCNQ1 | c.949del p.D317Tfs*37 | Frame Shift Del (DEL) | VAF 237/909 reads (26%) | catalogued as CM022806, CM055343; called by mutect2, pindel, varscan2
- KRT6B | c.1624G>C p.V542L | Missense Mutation (SNP) | VAF 26/485 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99360631; called by muse, mutect2
- MAGEB2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs761837486; called by muse, mutect2, varscan2
- MPDZ | c.1801del p.E601Kfs*2 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as COSV59945051; called by mutect2, pindel, varscan2
- MTHFS | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 125/522 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762045886; called by muse, mutect2, varscan2
- MXRA5 | c.3113C>A p.T1038K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV54235271; called by muse, mutect2, varscan2
- NACA | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100771542, COSV100771750; called by muse, mutect2
- OR4K2 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs532614465, COSV100064681, COSV53849963; called by muse, mutect2
- OXSM | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 58/139 reads (42%) | catalogued as rs760886044; called by muse, mutect2, varscan2
- PCDHGA9 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as rs377687399; called by muse, mutect2, varscan2
- PKD1L2 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 172/688 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs562980257; called by muse, mutect2, varscan2
- PLEKHA6 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768992797; called by muse, mutect2, varscan2
- PTPRS | c.3997C>T p.H1333Y | Missense Mutation (SNP) | VAF 117/360 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs367722276; called by muse, mutect2, varscan2
- SETD2 | c.7431+1del p.X2477_splice | Splice Site (DEL) | VAF 21/64 reads (33%) | catalogued as COSV57451000, COSV57454136; called by mutect2, pindel, varscan2
- TKTL2 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54917889; called by muse, mutect2, varscan2
- TSHZ3 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs756213628; called by muse, varscan2
- ADAMTS3 | c.3151A>T p.S1051C | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- AHCTF1 | c.2741_2742insACGTTATCCTTCA p.H914Qfs*12 (on ENST00000366508; = p.H888Qfs*12 on NM_015446.5) | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- AOC3 | c.711del p.F238Sfs*11 | Frame Shift Del (DEL) | VAF 72/296 reads (24%) | called by mutect2, varscan2
- AP2A2 | c.2745G>A p.M915I | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ASAP1 | c.1174A>T p.R392* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- CCDC18 | c.2581G>T p.E861* (on ENST00000343253 / NM_001306076.1; = p.E862* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- CDH15 | c.2080G>T p.G694C | Missense Mutation (SNP) | VAF 145/560 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CLTC | c.3128A>T p.Y1043F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, varscan2
- CSPG4 | c.4885G>C p.G1629R | Missense Mutation (SNP) | VAF 83/306 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2S1 | c.571T>A p.F191I | Missense Mutation (SNP) | VAF 141/504 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CYP7B1 | c.1214A>T p.E405V | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DEF6 | c.1250A>T p.K417M | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- DPP10 | c.2384A>T p.D795V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DYNC1H1 | c.13868A>G p.D4623G | Missense Mutation (SNP) | VAF 29/896 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.438); called by muse, mutect2
- F13B | c.1227C>A p.D409E | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- FAM155B | c.836T>G p.I279S | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2
- FBXL18 | c.1304C>A p.A435E | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FOXO6 | c.1240C>G p.L414V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.55); called by muse, mutect2, varscan2
- GPRASP1 | c.492T>A p.F164L | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GTF3C3 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- IFIT5 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIR2DL1 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 92/332 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KPNA4 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LCOR | c.797dup p.T267Hfs*9 | Frame Shift Ins (INS) | VAF 51/164 reads (31%) | called by mutect2, pindel, varscan2
- LRRK2 | c.7426A>T p.N2476Y | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAN2B1 | c.2168A>C p.D723A | Missense Mutation (SNP) | VAF 211/843 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MUC6 | c.4388T>A p.I1463N | Missense Mutation (SNP) | VAF 180/943 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.328); called by muse, varscan2
- NDST1 | c.1236C>A p.N412K | Missense Mutation (SNP) | VAF 111/409 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- NEB | c.8203C>T p.H2735Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NOL8 | c.3499A>G p.K1167E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PCDH7 | c.2066A>T p.N689I | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA6 | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 116/412 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PDZD2 | c.4943A>G p.K1648R | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PREX2 | c.2344G>T p.D782Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSMD12 | c.599T>G p.I200S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- RPS6KB2 | c.25T>A p.L9M | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SFI1 | c.1355T>A p.L452Q (on ENST00000400288 / NM_001007467.3; = p.L421Q on NM_014775.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SLC22A23 | c.1283G>C p.W428S | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC6A15 | c.1357T>G p.F453V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC6A3 | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 157/608 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLITRK6 | c.91T>C p.C31R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SORBS2 | c.2996A>G p.K999R (on ENST00000284776 / NM_021069.5; = p.K565R on NM_003603.6) | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SP5 | c.671C>G p.A224G | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUPT7L | c.944del p.P315Hfs*17 | Frame Shift Del (DEL) | VAF 42/140 reads (30%) | called by mutect2, pindel, varscan2
- TGM5 | c.1493C>T p.S498F (on ENST00000220420 / NM_201631.4; = p.S416F on NM_004245.4) | Missense Mutation (SNP) | VAF 20/555 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.127); called by muse, mutect2
- TOX | c.998T>A p.V333E | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TPST1 | c.904T>C p.W302R | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM3 | c.606T>A p.S202R | Missense Mutation (SNP) | VAF 136/424 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TTC29 | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VSTM5 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR72 | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ZNF317 | c.226del p.S76Lfs*10 | Frame Shift Del (DEL) | VAF 35/130 reads (27%) | called by mutect2, pindel, varscan2
- ZNF423 | c.733C>A p.L245M (on ENST00000563137 / NM_001379286.1; = p.L237M on NM_015069.4) | Missense Mutation (SNP) | VAF 124/446 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF528 | c.1789A>G p.R597G | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ACBD4 | c.789G>A p.L263= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- CDIN1 | c.7C>T p.L3= | Silent (SNP) | VAF 67/200 reads (34%) | called by muse, mutect2, varscan2
- CEACAM5 | c.1374C>T p.H458= | Silent (SNP) | VAF 95/449 reads (21%) | called by muse, mutect2, varscan2
- COL6A2 | c.2622C>T p.N874= | Silent (SNP) | VAF 302/1050 reads (29%) | catalogued as rs138270307; called by muse, varscan2
- CPXM2 | c.912C>T p.R304= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV53869957; called by muse, mutect2, varscan2
- DEF6 | c.1248G>T p.L416= | Silent (SNP) | VAF 40/174 reads (23%) | called by muse, mutect2
- DVL2 | c.636C>T p.D212= | Silent (SNP) | VAF 64/273 reads (23%) | catalogued as rs903803977, COSV50034699; called by muse, mutect2, varscan2
- ESRP1 | c.1254G>A p.S418= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs368354464; called by muse, mutect2, varscan2
- FAM122A | c.732T>G p.L244= | Silent (SNP) | VAF 96/424 reads (23%) | called by muse, mutect2, varscan2
- GABRQ | c.1404T>C p.F468= | Silent (SNP) | VAF 14/363 reads (4%) | called by muse, mutect2
- ISX | c.282G>T p.L94= | Silent (SNP) | VAF 77/260 reads (30%) | called by muse, mutect2, varscan2
- LAMB1 | c.4602T>C p.P1534= | Silent (SNP) | VAF 47/210 reads (22%) | called by muse, mutect2, varscan2
- MAGEB6B | c.249T>C p.D83= | Silent (SNP) | VAF 122/433 reads (28%) | called by muse, mutect2, varscan2
- MAPK4 | c.417C>T p.Y139= | Silent (SNP) | VAF 39/226 reads (17%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.1392G>A p.P464= | Silent (SNP) | VAF 58/314 reads (18%) | catalogued as rs534677823, COSV53573576; called by muse, mutect2, varscan2
- RHOQ | c.246T>C p.D82= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs939342712; called by muse, mutect2, varscan2
- RNF11 | c.243T>C p.P81= | Silent (SNP) | VAF 46/158 reads (29%) | called by muse, mutect2, varscan2
- RPRD1B | c.744G>T p.L248= | Silent (SNP) | VAF 102/402 reads (25%) | called by muse, mutect2, varscan2
- SCNN1A | c.783G>A p.S261= | Silent (SNP) | VAF 148/474 reads (31%) | catalogued as rs72645110; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC30A2 | c.204G>T p.G68= | Silent (SNP) | VAF 102/471 reads (22%) | called by muse, mutect2, varscan2
- AP001267.5 | c.-868A>C | 5'UTR (SNP) | VAF 108/399 reads (27%) | catalogued as rs1565544870; called by muse, mutect2, varscan2
- ARR3 | c.1076+46T>A | Intron (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- CCDC150 | c.1441-165G>T | Intron (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
- LHX1 | c.-416A>T | 5'UTR (SNP) | VAF 59/258 reads (23%) | called by muse, mutect2, varscan2
- MON2 | chr12:62603757 T>C | 3'Flank (SNP) | VAF 110/520 reads (21%) | called by muse, mutect2, varscan2
- MRPL4 | c.-11G>T | 5'UTR (SNP) | VAF 57/194 reads (29%) | catalogued as rs557558402; called by muse, mutect2, varscan2
- PRCP | chr11:82900670 C>G | 5'Flank (SNP) | VAF 96/400 reads (24%) | called by muse, mutect2, varscan2
- RCOR3 | chr1:211259662 del GTCCACCAACGGCG | 5'Flank (DEL) | VAF 30/160 reads (19%) | called by mutect2, pindel, varscan2
- RIF1 | c.-467G>A | 5'UTR (SNP) | VAF 190/676 reads (28%) | catalogued as rs1383302935; called by muse, mutect2, varscan2
- SAG | c.181+72G>T | Intron (SNP) | VAF 158/537 reads (29%) | called by muse, mutect2, varscan2
- TBX6 | c.*8C>A | 3'UTR (SNP) | VAF 106/421 reads (25%) | called by muse, mutect2, varscan2
- TUBB4B | c.-63C>T | 5'UTR (SNP) | VAF 107/402 reads (27%) | catalogued as rs1222659101; called by muse, mutect2, varscan2
